Somatic mutation profile of tumor specimen C3N-03789-05 (aliquot CPT0244860006) from CPTAC case C3N-03789, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.4 years (29,377 days).
Specimen C3N-03789-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 899417f9-4e7c-4cf7-b994-ec193e05d5e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03789-31 (Blood Derived Normal), aliquot CPT0244880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d86695c-1247-4066-a95f-2754b177a593

The open-access MAF lists 73 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Intron 9, Nonsense Mutation 4, Frame Shift Del 4, RNA 4, 3'UTR 2, 5'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 100/254 reads (39%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 87/445 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AQR | c.3991C>T p.H1331Y | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1049194354; called by muse, mutect2, varscan2
- ATP4A | c.2317G>A p.V773M | Missense Mutation (SNP) | VAF 61/385 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs761437112, COSV52868459; called by muse, mutect2, varscan2
- CACNA2D4 | c.3181T>C p.C1061R | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54964967; called by muse, mutect2, varscan2
- CBFA2T3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753386888, COSV51929695; called by muse, mutect2, varscan2
- CCDC39 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs776582538; called by muse, mutect2, varscan2
- CDH7 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs761625164; called by muse, mutect2, varscan2
- CFAP46 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781779542; called by muse, mutect2, varscan2
- F13B | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.102); catalogued as rs756567129; called by muse, mutect2, varscan2
- GP1BB | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 130/482 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1238007919; called by muse, mutect2, varscan2
- IARS2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as rs1352084435; called by muse, mutect2, varscan2
- INTS4 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as rs763345688, COSV101417131; called by muse, mutect2, varscan2
- KCNB1 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs372263564; ClinVar: benign; called by muse, mutect2, varscan2
- KHSRP | c.1742C>G p.S581* | Nonsense Mutation (SNP) | VAF 38/182 reads (21%) | catalogued as COSV67919676; called by muse, mutect2, varscan2
- MUC12 | c.2326A>G p.T776A (on ENST00000379442; = p.T633A on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/1384 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); catalogued as rs1159943368; called by muse, mutect2
- PCSK5 | c.3962G>A p.G1321E | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV70449001; called by muse, mutect2, varscan2
- PGAM5 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs1372520922; called by muse, mutect2
- PHF20 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772978047, COSV100179955; called by muse, mutect2, varscan2
- PLA2G4E | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780827581; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs146650273; called by pindel, varscan2
- RBMXL2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60978701; called by muse, mutect2, varscan2
- RIPK3 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs1194239642; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SDCCAG8 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs190020173, COSV59409406; called by muse, mutect2, varscan2
- SMIM21 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs375362339, COSV66894840; called by muse, mutect2
- STXBP2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs539611010, CD1313330; called by muse, mutect2, varscan2
- SUSD6 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as rs371600178; called by muse, mutect2
- TRIO | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60096576; called by muse, mutect2, varscan2
- VARS1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs763478263; called by muse, mutect2, varscan2
- ABCA10 | c.4015A>C p.T1339P | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ARHGAP21 | c.1575_1578del p.Y526Sfs*46 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- C2orf16 | c.93_94del p.S33Qfs*21 | Frame Shift Del (DEL) | VAF 24/190 reads (13%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.1935A>G p.I645M (on ENST00000389672 / NM_001080448.3; = p.I37M on NM_173655.4) | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 88/580 reads (15%) | SIFT deleterious, low confidence (0.04); called by mutect2, varscan2
- KSR2 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPHOSPH9 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MYH8 | c.4445C>G p.T1482S | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLK2 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RTN4R | c.695_698del p.Y232Cfs*23 | Frame Shift Del (DEL) | VAF 151/697 reads (22%) | called by mutect2, pindel, varscan2
- SIRPB1 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ACTL7A | c.1203C>T p.T401= | Silent (SNP) | VAF 46/196 reads (23%) | catalogued as rs752301041, COSV100453279; called by muse, mutect2, varscan2
- C8orf82 | c.420C>T p.F140= | Silent (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.8955C>T p.D2985= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs945431003; called by muse, mutect2, varscan2
- EYS | c.7608C>T p.I2536= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs562496683, COSV65489635; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP26-1 | c.333C>G p.S111= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100860478; called by muse, mutect2, varscan2
- N4BP3 | c.453G>A p.T151= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as rs374439291; called by muse, mutect2, varscan2
- OR3A1 | c.504G>A p.T168= | Silent (SNP) | VAF 105/494 reads (21%) | catalogued as rs201559764, COSV60162478, COSV60163359; called by muse, mutect2, varscan2
- POLR3A | c.273G>A p.P91= | Silent (SNP) | VAF 98/318 reads (31%) | catalogued as rs752246988; called by mutect2, varscan2
- RELN | c.2016G>A p.P672= | Silent (SNP) | VAF 42/264 reads (16%) | catalogued as rs146749232, COSV59016458; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SPATA21 | c.330C>A p.A110= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs746980477; called by muse, mutect2, varscan2
- STRIP1 | c.2001T>G p.S667= | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- TLR1 | c.1683T>C p.S561= | Silent (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.606A>G p.R202= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ZNF613 | c.597C>T p.N199= (on ENST00000293471 / NM_001031721.4; = p.N163= on NM_024840.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV53271153; called by muse, mutect2, varscan2
- AC023469.1 | n.245dup | RNA (INS) | VAF 25/162 reads (15%) | called by mutect2, pindel, varscan2
- ADAM3A | n.2057C>T | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- BCAM | c.504+10G>A | Intron (SNP) | VAF 38/205 reads (19%) | catalogued as rs779126630; called by muse, mutect2, varscan2
- CCDC175 | c.2305+150T>C | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs761005799; called by muse, mutect2
- EPB41L3 | c.-11-36C>T | Intron (SNP) | VAF 25/122 reads (20%) | catalogued as rs781033176; called by muse, mutect2, varscan2
- LINC01559 | n.616C>T | RNA (SNP) | VAF 30/125 reads (24%) | catalogued as rs565851634; called by muse, mutect2, varscan2
- MSR1 | c.1033+2482T>A | Intron (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- NXPH3 | c.*2535_*2537del | 3'UTR (DEL) | VAF 26/86 reads (30%) | called by pindel, varscan2
- PHF14 | c.*4C>A | 3'UTR (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791532 C>A | 3'Flank (SNP) | VAF 80/238 reads (34%) | called by muse, mutect2, varscan2
- SH3TC1 | c.173-71C>T | Intron (SNP) | VAF 75/355 reads (21%) | catalogued as rs771178324; called by muse, mutect2, varscan2
- SLC6A19 | c.-7G>A | 5'UTR (SNP) | VAF 96/410 reads (23%) | catalogued as rs779161770; called by muse, mutect2, varscan2
- TMEM235 | c.271+265C>G | Intron (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.42952+51G>T | Intron (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- VGLL4 | c.64+31671G>A | Intron (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3812del | Intron (DEL) | VAF 32/273 reads (12%) | called by mutect2, pindel, varscan2
- ZNF286B | n.1049T>C | RNA (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
